Somatic mutation profile of tumor specimen TCGA-BQ-7050-01A (aliquot TCGA-BQ-7050-01A-11D-1961-08) from TCGA case TCGA-BQ-7050, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 53.5 years (19,550 days).
Specimen TCGA-BQ-7050-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7652aac-b9a6-4601-a147-fa6fcf501025.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-7050-11A (Solid Tissue Normal), aliquot TCGA-BQ-7050-11A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/230c6c60-42ff-4835-81ea-41efd998f1f4

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Del 1, RNA 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASH1L | c.7651T>C p.S2551P (on ENST00000368346 / NM_001366177.2; = p.S2546P on NM_018489.3) | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.355); catalogued as COSV64210423; called by muse, mutect2, varscan2
- DNAJC13 | c.1898T>C p.L633P | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53453990; called by muse, mutect2, varscan2
- EPHB6 | c.2755A>G p.M919V | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV63892558; called by muse, mutect2, varscan2
- FBXW5 | c.428T>G p.F143C | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56403484; called by muse, mutect2, varscan2
- NEK7 | c.212T>G p.M71R | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV66315474; called by muse, mutect2, varscan2
- NTRK2 | c.941C>G p.A314G | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV52871107; called by muse, mutect2, varscan2
- PCF11 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs779536068, COSV53532396; called by muse, mutect2, varscan2
- TCERG1 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs769612257, COSV57039195; called by muse, mutect2, varscan2
- XRN1 | c.923C>G p.P308R | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53814659; called by muse, mutect2
- ZFC3H1 | c.4502T>A p.L1501* | Nonsense Mutation (SNP) | VAF 39/203 reads (19%) | catalogued as COSV66434194; called by muse, mutect2, varscan2
- ZNF532 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as rs761224418, COSV60174357; called by muse, mutect2, varscan2
- ZNF615 | c.1241G>T p.C414F | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.029); catalogued as COSV65034210; called by muse, mutect2, varscan2
- ATP1B1 | c.63del p.K22Rfs*19 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- ZNF440 | c.1492_1494del p.V498del | In Frame Del (DEL) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- PAN2 | c.1203A>G p.P401= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV57754674; called by muse, mutect2, varscan2
- THBS1 | c.2016C>G p.P672= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV52953833; called by muse, mutect2, varscan2
- ZFP36 | c.63T>C p.P21= (on ENST00000594442; = p.P15= on NM_003407.5) | Silent (SNP) | VAF 92/264 reads (35%) | catalogued as COSV50529416; called by muse, mutect2, varscan2
- AC024940.1 | n.4224G>A | RNA (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
